TCGA case TCGA-3H-AB3X — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Bronchus and lung; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c739fd61-22b2-412d-bcf3-89bda45a2c0f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Epithelioid mesothelioma, malignant: ICD-O-3 morphology code: 9052/3; ICD-10 code: C34.90; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 62.2 years (22,702 days); Year of diagnosis: 2010; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,490 days (4.1 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Dasatinib; Days to treatment start: 91 days; Days to treatment end: 123 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 236 days; Days to treatment end: 271 days; Treatment dose: 45 Gy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 435 days (1.2 years); Days to treatment end: 461 days (1.3 years); Treatment outcome: Complete Response.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.

Follow-up (4 entries)
- Days to follow up: 803 days (2.2 years); Disease response: Tumor Free.
- Days to follow up: 1,490 days (4.1 years); Disease response: Tumor Free.
- Imaging anatomic site: Pleura; Imaging suv max: 9.5; Timepoint: Prior to Treatment.
- ECOG performance status: 0; Timepoint: Preoperative.

Molecular and laboratory tests
- Creatinine 0.92 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.3].

Exposures
- Occupation duration years: 30; Occupation type: Process Control Technicians.
- Exposure type: Asbestos; Exposure source: Occupational.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3H-AB3X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 60 mg.
  Slide TCGA-3H-AB3X-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 10.
- Sample TCGA-3H-AB3X-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3H-AB3X-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: Tumor free; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: petrochemical industry; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,490 days; disease-specific survival: no event (censored), 1,490 days; progression-free interval: no event (censored), 1,490 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3H-AB3X-01A-11D-A39Q-01): tumor purity 0.74, ploidy 2.01, whole-genome doublings 0.
